Gene-level copy-number profile of tumor specimen TCGA-19-5954-01A from TCGA case TCGA-19-5954, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.2 years (26,355 days).
Specimen TCGA-19-5954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.68999b3c-ce1e-448b-95bb-60983d54adee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-5954-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16e45c42-716a-4ab2-af2c-d8a343d1be3d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 2: 2,843; copy number 3: 399; copy number 4: 51,993; copy number 6: 1,471; copy number 7: 2,950; copy number 8: 21; copy number 12: 9; copy number 17: 16; copy number 18: 4; copy number 20: 1; copy number 23: 4; copy number 33: 6; copy number 36: 3; copy number 40: 33; copy number 47: 2; copy number 49: 3; copy number 56: 28; copy number 69: 4; copy number 70: 8; copy number 79: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-5954-01A-11D-1694-01): tumor purity 0.8, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,128,103, 17 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 124 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,377,850–205,134,950, 21 genes, copy number 40 (within-gene range 3–40): AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2.
- chr5:710,355–956,520, 9 genes, copy number 12: ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1.
- chr5:1,225,381–1,350,786, 6 genes, copy number 33: SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7.
- chr5:9,854,371–9,899,970, 1 gene, copy number 23: LINC02221.
- chr5:10,353,695–10,472,029, 3 genes, copy number 49 (within-gene range 2–49): MARCHF6, ROPN1L-AS1, ROPN1L.
- chr7:54,185,071–56,229,782, 58 genes, copy number 17–69: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1.
- chr12:3,606,633–4,305,353, 12 genes, copy number 40: CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2.
- chr21:14,371,115–14,383,484, 1 gene, copy number 20: HSPA13.
- chr21:14,818,843–15,014,430, 2 genes, copy number 70 (within-gene range 2–70): AF127577.4, LINC02246.
- chr21:14,918,534–15,067,837, 6 genes, copy number 70: AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5.
- chr21:15,263,421–15,346,738, 2 genes, copy number 47: AF130248.1, AF246928.1.
- chr21:16,035,413–16,121,644, 3 genes, copy number 79: RNU6-426P, VDAC2P1, RPS26P5.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
